Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA38, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA38-01A (Primary Tumor).

Female

DATE:

DIAGNOSIS:

A. Liver, segments I, II, III, and IV, partial hepatectomy: Poorly differentiated adenocarcinoma, consistent with cholangiocarcinoma, is identified forming a single 11.8 x 8.2 x 6.1 cm mass confined to the hepatic parenchyma. Major vessel invasion is absent. Microscopic vascular invasion is absent. Multiple (3) regional lymph nodes are negative for tumor. The adjacent liver parenchyma shows mild portal lymphocytic inflammatory infiltrate.

ICD O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

9/3/8/14

Source: NCI Genomic Data Commons file d451eb4b-ca8d-4398-a033-ae0d9e8cf7c8 (TCGA-W5-AA38.626B6057-4EFB-4AC9-A761-6759D5EF9EC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).